Somatic mutation profile of tumor specimen TCGA-3M-AB47-01A (aliquot TCGA-3M-AB47-01A-22D-A410-08) from TCGA case TCGA-3M-AB47, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3.
Specimen TCGA-3M-AB47-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21deceb1-d3bb-4f21-9a03-c8e4a8124101.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3M-AB47-10A (Blood Derived Normal), aliquot TCGA-3M-AB47-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91ff1256-3d9a-4383-94a7-34fd52ecd88a

The open-access MAF lists 126 somatic variants for this specimen: 94 protein-altering or splice-affecting, 26 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 26, Nonsense Mutation 4, Frame Shift Ins 4, RNA 3, Splice Site 2, Intron 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KAT8 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 19/71 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54896480; called by muse, mutect2, varscan2
- KMT2C | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | hotspot (GDC flag); catalogued as rs1283285486, COSV51288537; called by muse, mutect2, varscan2
- ACSBG1 | c.1406G>C p.R469P | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs748664490, COSV51903267, COSV99357652, COSV99357780; called by muse, mutect2, varscan2
- AKAP12 | c.1486G>A p.V496I | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374740675; called by muse, mutect2, varscan2
- ASCC3 | c.801+1G>T p.X267_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as rs1432792609, COSV100226096; called by muse, varscan2
- BNC2 | c.1296G>A p.M432I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.191); catalogued as COSV101033953; called by muse, mutect2, varscan2
- CCDC121 | c.193dup p.S65Kfs*5 | Frame Shift Ins (INS) | VAF 32/155 reads (21%) | catalogued as rs762148159; called by mutect2, pindel, varscan2
- CDH1 | c.687+1G>T p.X229_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as CS041879, COSV99931572, COSV99932405; called by muse, mutect2, varscan2
- CDH6 | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV99420140; called by muse, mutect2, varscan2
- CDH8 | c.872T>G p.L291R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV54856481, COSV54868032, COSV54899386; called by muse, mutect2, varscan2
- CMYA5 | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1244790577, COSV71405373; called by muse, mutect2, varscan2
- COL12A1 | c.5851G>A p.D1951N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs771175230, COSV100486283; called by muse, mutect2, varscan2
- COL15A1 | c.2972C>A p.S991Y | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100897873; called by mutect2, varscan2
- CRMP1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs1183227411, COSV100272161; called by muse, mutect2, varscan2
- CRX | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as COSV99704603; called by muse, mutect2, varscan2
- CTNNA3 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1299153203, COSV101041512; called by muse, mutect2, varscan2
- DCLK1 | c.384T>G p.S128R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99712346; called by muse, varscan2
- DDX21 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); catalogued as COSV100826538; called by muse, mutect2, varscan2
- DHX37 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1029574157, COSV100439386; called by muse, mutect2, varscan2
- DNAH1 | c.3796C>T p.R1266C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs755852298, COSV101326579; called by muse, mutect2
- DOCK8 | c.6184G>A p.E2062K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.087); catalogued as rs201733542; called by muse, mutect2, varscan2
- DPYSL2 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs1159884667, COSV100234041; called by muse, mutect2
- EFCAB1 | c.530A>G p.E177G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100030603; called by muse, mutect2, varscan2
- EIF4G3 | c.2221A>G p.S741G | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99945098; called by muse, mutect2, varscan2
- ELP1 | c.3599C>T p.A1200V | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs776976107, COSV101010444; called by muse, mutect2, varscan2
- FAT4 | c.10648T>G p.L3550V | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100629436; called by muse, mutect2, varscan2
- FLRT2 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV100420759, COSV58140326; called by muse, mutect2, varscan2
- FN1 | c.2180C>A p.S727Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100117757; called by muse, mutect2, varscan2
- FZD2 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866012347, COSV59528298; called by muse, mutect2, varscan2
- GTDC1 | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV99601297; called by muse, mutect2, varscan2
- GYS2 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs958670031, COSV53925338; called by muse, mutect2, varscan2
- HCN1 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as COSV57517666; called by muse, mutect2, varscan2
- HERPUD2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1341275029, COSV60947739; called by muse, mutect2, varscan2
- HOMER1 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1339072500, COSV56523799, COSV99981273; called by muse, mutect2, varscan2
- HPN | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.142); catalogued as rs752238031, COSV99385246; called by muse, mutect2, varscan2
- HTR2A | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66327203; called by muse, mutect2, varscan2
- KMT2B | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs1486195468, COSV52892387, COSV99386175; called by muse, mutect2
- KMT2B | c.7879G>A p.G2627R | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99495325; called by muse, mutect2
- KMT2D | c.13030C>T p.P4344S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.13); catalogued as COSV56485447; called by muse, mutect2
- LAMA1 | c.5567T>A p.V1856D | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV101057128; called by muse, mutect2, varscan2
- LAMA1 | c.5329G>A p.E1777K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV67541572; called by muse, mutect2, varscan2
- LAMA1 | c.1488C>A p.N496K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs781121049, COSV67533529, COSV67540434; called by muse, mutect2, varscan2
- LCE1B | c.132C>A p.C44* | Nonsense Mutation (SNP) | VAF 17/86 reads (20%) | catalogued as COSV100780302; called by muse, mutect2, varscan2
- LCE2D | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.037); catalogued as rs113433987; called by muse, mutect2, varscan2
- LRP1B | c.12511G>T p.D4171Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1367688328, COSV101258779; called by muse, mutect2, varscan2
- LTBP4 | c.4765G>A p.V1589I (on ENST00000308370 / NM_001042544.1; = p.V1552I on NM_003573.2) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99198956; called by muse, mutect2, varscan2
- M1AP | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99304350; called by muse, mutect2, varscan2
- MUC5B | c.14698G>A p.V4900M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs200106435; called by muse, mutect2, varscan2
- MYH7 | c.626A>G p.Q209R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV100806392; called by muse, mutect2, varscan2
- NAV3 | c.6197C>A p.A2066E (on ENST00000397909 / NM_001024383.2; = p.A2044E on NM_014903.6) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99893707; called by muse, mutect2, varscan2
- NBR1 | c.1670C>G p.A557G | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100357938; called by muse, mutect2, varscan2
- NF1 | c.1319G>C p.R440P | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100647812, COSV62201290; called by muse, mutect2, varscan2
- NLRP14 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.613); catalogued as COSV100205258, COSV55072729; called by muse, mutect2, varscan2
- NOL4 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99307724; called by muse, mutect2
- NOX3 | c.1228G>T p.G410* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV50154109, COSV99343503; called by muse, mutect2, varscan2
- NSD1 | c.7550G>A p.G2517E | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as COSV100729649; called by muse, mutect2, varscan2
- OLFM3 | c.1246G>A p.V416M (on ENST00000338858 / NM_001288821.1; = p.V396M on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58798907; called by muse, mutect2, varscan2
- OPRM1 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.98); catalogued as COSV100001980, COSV57681042; called by muse, mutect2, varscan2
- OR51B5 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as COSV100332625; called by muse, mutect2, varscan2
- OR6C4 | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV67792990; called by muse, mutect2, varscan2
- PCDH10 | c.2062G>A p.G688R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.515); catalogued as COSV99994143; called by muse, mutect2, varscan2
- PCDH11Y | c.2596G>T p.V866L (on ENST00000400457 / NM_032973.2; = p.V855L on NM_032971.3) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.196); catalogued as COSV99292229; called by muse, mutect2, varscan2
- PHKB | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774459319, COSV100068052; called by muse, mutect2, varscan2
- PRAMEF19 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as rs758393659; called by muse, mutect2, varscan2
- PRICKLE4 | c.233A>G p.K78R (on ENST00000359201; = p.K118R on NM_013397.6) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100138826; called by muse, mutect2
- PXDN | c.1804T>A p.S602T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.065); catalogued as COSV99414351; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2282C>T p.S761L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as rs562096116, COSV100741385; called by muse, mutect2, varscan2
- RANBP2 | c.7946C>G p.T2649S | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99312791; called by muse, mutect2, varscan2
- RHOA | c.77G>T p.S26I | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV101371153, COSV69041919; called by muse, mutect2, varscan2
- SALL1 | c.2332G>A p.A778T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1441384433, COSV99177992; called by muse, mutect2, varscan2
- SBNO1 | c.4006C>T p.R1336W (on ENST00000420886; = p.R1335W on NM_018183.5) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV57339340; called by muse, mutect2, varscan2
- SCN4A | c.3172C>T p.R1058W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764018183, COSV71127329; called by muse, mutect2, varscan2
- SCN5A | c.6001C>T p.L2001F (on ENST00000333535 / NM_198056.3; = p.L2000F on NM_000335.5) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100349683; called by muse, mutect2, varscan2
- SERTAD4 | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV100882645; called by muse, mutect2, varscan2
- SLC20A2 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as rs368076501; called by muse, mutect2, varscan2
- SPG11 | c.2881C>T p.L961F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99969203; called by muse, mutect2, varscan2
- SYT3 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100144227; called by muse, mutect2, varscan2
- TGM5 | c.1105G>A p.G369S (on ENST00000220420 / NM_201631.4; = p.G287S on NM_004245.4) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs368075847; called by muse, mutect2, varscan2
- TMEM63C | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100029610; called by muse, mutect2, varscan2
- TOX2 | c.586G>A p.A196T (on ENST00000358131 / NM_001098798.2; = p.A145T on NM_032883.3) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs761415679, COSV100364346; called by muse, mutect2, varscan2
- TSKU | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV100290167, COSV60750753; called by muse, mutect2, varscan2
- TTC21A | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100073233; called by muse, mutect2, varscan2
- WDPCP | c.576G>T p.K192N | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99706134; called by muse, mutect2
- WIPF2 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs761403770, COSV60272466; called by muse, mutect2
- ZFHX4 | c.1885G>A p.G629S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99265674; called by muse, mutect2, varscan2
- ZIC4 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746281542, COSV67172376; called by muse, mutect2, varscan2
- ZMAT1 | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.182); catalogued as COSV100858883; called by muse, mutect2, varscan2
- ZNF347 | c.1457A>T p.K486M | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs1357434987, COSV100498362; called by muse, mutect2, varscan2
- ZNF470 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100401329; called by muse, mutect2, varscan2
- ZNF681 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV101267534; called by muse, mutect2, varscan2
- ARMC2 | c.1381dup p.S461Ffs*7 | Frame Shift Ins (INS) | VAF 18/107 reads (17%) | called by mutect2, pindel, varscan2
- ATP1A2 | c.1631dup p.L545Tfs*28 | Frame Shift Ins (INS) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- HEY2 | c.243del p.K81Nfs*7 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- PIGR | c.1458dup p.K487Qfs*14 | Frame Shift Ins (INS) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- BAZ2A | c.372C>T p.N124= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs750227920, COSV99467033; called by muse, mutect2, varscan2
- BMP10 | c.465T>C p.R155= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99770521; called by muse, mutect2, varscan2
- CCN4 | c.510G>A p.P170= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs775016662, COSV51530348; called by muse, mutect2
- CIP2A | c.984C>T p.S328= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs761531535, COSV55417270; called by muse, mutect2, varscan2
- COL4A2 | c.2067A>G p.P689= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100847429; called by muse, mutect2, varscan2
- CYP20A1 | c.612G>A p.E204= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100619099; called by muse, mutect2
- DLC1 | c.2736C>T p.H912= (on ENST00000276297 / NM_001348081.2; = p.H475= on NM_006094.5) | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99360192; called by muse, mutect2
- DYRK2 | c.1467C>T p.G489= (on ENST00000344096 / NM_006482.3; = p.G416= on NM_003583.4) | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1398705159, COSV100165357; called by muse, mutect2, varscan2
- FAM135B | c.2802G>T p.V934= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV99425953; called by muse, mutect2, varscan2
- FDX1 | c.366C>T p.H122= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV99501906; called by muse, mutect2, varscan2
- GPR151 | c.975A>C p.I325= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99695104; called by muse, mutect2, varscan2
- GRID2 | c.2058G>A p.A686= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs754576771, COSV56169267; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNB2 | c.1464G>A p.S488= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs201431676, COSV73049247; called by muse, mutect2, varscan2
- KCTD19 | c.1617C>T p.F539= | Silent (SNP) | VAF 32/146 reads (22%) | catalogued as rs544017674, COSV100430891; called by muse, mutect2, varscan2
- KRT37 | c.858C>T p.T286= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV99845641; called by muse, mutect2, varscan2
- MAGI2 | c.2091A>C p.R697= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100835592; called by muse, mutect2, varscan2
- MYH6 | c.2841C>T p.D947= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs140305424; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR51E2 | c.150G>A p.T50= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs777889264; called by muse, mutect2, varscan2
- PLPP4 | c.744G>A p.K248= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100956473, COSV64827144; called by muse, mutect2
- PMM1 | c.108C>T p.A36= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs751486696, COSV53449797; called by muse, mutect2, varscan2
- RBM4B | c.27T>G p.L9= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs144151416; called by mutect2, varscan2
- RIMS2 | c.1299T>C p.P433= (on ENST00000666250 / NM_001348490.2; = p.P241= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV51682181; called by muse, mutect2, varscan2
- RNF123 | c.1234C>T p.L412= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100571012; called by muse, mutect2, varscan2
- SNRPN | c.477C>T p.A159= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100578432; called by muse, mutect2, varscan2
- ST18 | c.1590T>C p.P530= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV99390523; called by muse, mutect2
- TRIM46 | c.1356G>A p.L452= | Silent (SNP) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- AGAP7P | n.1402G>T | RNA (SNP) | VAF 9/88 reads (10%) | catalogued as rs1554941322; called by muse, mutect2, varscan2
- HTR2C | c.-80+38812C>A | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- HYDIN | c.*1T>C | 3'UTR (SNP) | VAF 7/60 reads (12%) | catalogued as COSV101125151; called by muse, mutect2, varscan2
- MIR543 | n.32G>A | RNA (SNP) | VAF 22/91 reads (24%) | catalogued as rs376020279; called by muse, mutect2, varscan2
- MORF4 | n.464A>C | RNA (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- NEDD4L | c.122+29859C>T | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99895962; called by muse, mutect2, varscan2
